Somatic mutation profile of tumor specimen TCGA-98-8022-01A (aliquot TCGA-98-8022-01A-11D-2244-08) from TCGA case TCGA-98-8022, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.6 years (22,487 days).
Specimen TCGA-98-8022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc63390-6246-4e7c-a2d8-4858739a0e6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-8022-10A (Blood Derived Normal), aliquot TCGA-98-8022-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caa3a73b-0483-45ad-9cfa-24071dfc751b

The open-access MAF lists 247 somatic variants for this specimen: 183 protein-altering or splice-affecting, 56 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 56, Nonsense Mutation 15, Splice Site 6, RNA 5, Frame Shift Del 4, Frame Shift Ins 2, 5'UTR 2, In Frame Del 1, Splice Region 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM12 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100900458; called by muse, mutect2
- ADGRL2 | c.2285C>G p.S762C (on ENST00000370717 / NM_001366005.1; = p.S749C on NM_012302.4) | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54669891; called by muse, mutect2, varscan2
- ALG3 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1198482018; called by muse, mutect2, varscan2
- ARHGAP28 | c.1931G>T p.R644L (on ENST00000383472 / NM_001366230.1; = p.R485L on NM_001010000.3) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51644838; called by muse, mutect2, varscan2
- ATP5F1C | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs755781927, COSV59621499; called by muse, mutect2, varscan2
- BAG4 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs778910259, COSV99781843; called by muse, mutect2, varscan2
- C2orf16 | c.2675T>C p.M892T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1054158213; called by muse, mutect2, varscan2
- C2orf68 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs375189288; called by muse, mutect2, varscan2
- CATSPERE | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs867029453, COSV63678140; called by muse, mutect2, varscan2
- CHI3L2 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV100869284; called by muse, mutect2, varscan2
- CHRNB3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251551; called by muse, mutect2
- COL4A2 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561349636, COSV64628838; called by muse, mutect2, varscan2
- DRICH1 | c.622-1G>C p.X208_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100497436; called by muse, mutect2, varscan2
- E2F7 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59737344; called by muse, mutect2, varscan2
- EMSY | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100595699, COSV58258669; called by muse, mutect2
- FAM47C | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100792907, COSV63730339; called by muse, mutect2, varscan2
- FREM1 | c.2140A>T p.T714S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66524266; called by muse, mutect2
- FZR1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV100553657; called by muse, mutect2, varscan2
- H3C2 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99451476; called by muse, mutect2
- HAS1 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372997311; called by muse, mutect2, varscan2
- HDAC9 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as COSV101286771; called by muse, varscan2
- HSPA14 | c.458dup p.N153Kfs*8 | Frame Shift Ins (INS) | VAF 10/67 reads (15%) | catalogued as rs775839750; called by mutect2, varscan2
- ITIH4 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750157544, COSV56573484; called by muse, mutect2, varscan2
- KDM4C | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV67187705; called by muse, mutect2, varscan2
- KLF12 | c.249C>A p.D83E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100888514; called by muse, mutect2
- KRT24 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52880276, COSV99232062; called by muse, mutect2
- LAMA2 | c.1272del p.V425Sfs*27 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | catalogued as COSV70340616; called by mutect2, pindel
- LCE1F | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1199594549, COSV57669177; called by muse, mutect2, varscan2
- MAGEL2 | c.2837G>C p.W946S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs527396971, COSV100046258; called by muse, mutect2
- MEI1 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs746239357; called by muse, mutect2, varscan2
- MUC4 | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100640473; called by muse, mutect2
- MUC4 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV100640474; called by muse, mutect2
- MYCBP2 | c.3649C>A p.R1217S (on ENST00000357337; = p.R1255S on NM_015057.5) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV62011603; called by muse, mutect2
- MYH9 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99338759; called by muse, mutect2
- MYT1L | c.1892A>T p.N631I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101219313; called by muse, mutect2, varscan2
- NADSYN1 | c.1047+2T>G p.X349_splice | Splice Site (SNP) | VAF 12/127 reads (9%) | catalogued as COSV100034708, COSV59815500; called by muse, mutect2
- NCCRP1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 117/359 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs113786921; called by muse, mutect2, varscan2
- NEO1 | c.3683C>G p.A1228G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1329982222; called by muse, mutect2, varscan2
- NLRP13 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs778748255, COSV61623859; called by muse, mutect2, varscan2
- NOTCH1 | c.6223G>T p.E2075* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as COSV53086155; called by muse, mutect2, varscan2
- OPN1SW | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs545093905, COSV50821563; called by muse, mutect2
- OR12D2 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs754906725; called by muse, mutect2, varscan2
- OR14I1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1028978016; called by muse, mutect2, varscan2
- OR1C1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV68715427; called by muse, mutect2, varscan2
- OR2M3 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 111/496 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1200497867; called by muse, mutect2, varscan2
- OR51V1 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468552462; called by muse, mutect2
- OR6T1 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100189650; called by muse, mutect2, varscan2
- OR8U1 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs372027293; called by muse, mutect2, varscan2
- PCDH9 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs959748851, COSV100120523, COSV60530780; called by muse, mutect2
- PCDHA4 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs147908793; called by muse, mutect2
- PSMC4 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs781289010; called by muse, mutect2
- PVRIG | c.657+2T>C p.X219_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99443827; called by muse, mutect2, varscan2
- RASA1 | c.1610+1del | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as COSV57195093; called by mutect2, pindel, varscan2
- REM1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs749761528, COSV52429909; called by muse, varscan2
- RFC3 | c.711-1G>T p.X237_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV101197821; called by muse, mutect2, varscan2
- RGS7 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58547558, COSV58555678; called by muse, mutect2, varscan2
- RNF113B | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs1055732127; called by muse, mutect2, varscan2
- RXRG | c.453C>A p.Y151* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV63232076; called by muse, mutect2, varscan2
- SCCPDH | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs758067910; called by muse, mutect2, varscan2
- SCN11A | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV56568836; called by muse, mutect2, varscan2
- SLC35E4 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.259); catalogued as COSV55898721; called by muse, mutect2, varscan2
- SLC6A9 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs200633191; called by muse, mutect2, varscan2
- SLC9B1 | c.1434G>T p.L478F | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56469846, COSV56470599; called by muse, mutect2
- SPHKAP | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751963020; called by muse, mutect2, varscan2
- SUGT1 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs781485813; called by muse, mutect2, varscan2
- TADA2A | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1200288414; called by muse, mutect2, varscan2
- TCF25 | c.2030G>C p.*677Sext*26 | Nonstop Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV54531178, COSV99642391; called by muse, mutect2
- TCHH | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 6/161 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100915047, COSV64278140; called by muse, mutect2
- TDRD7 | c.2991C>G p.H997Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777982037, COSV62428578; called by muse, mutect2, varscan2
- TGFB1I1 | c.636G>C p.Q212H (on ENST00000394863 / NM_001042454.3; = p.Q195H on NM_015927.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100691034; called by muse, mutect2
- TMEM225 | c.328+2T>G p.X110_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100902807; called by muse, mutect2, varscan2
- TOX2 | c.608C>T p.P203L (on ENST00000358131 / NM_001098798.2; = p.P152L on NM_032883.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs559758657, COSV57884783; called by muse, mutect2, varscan2
- TRIM51 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55269118, COSV99792579; called by muse, mutect2, varscan2
- TRPS1 | c.409C>G p.Q137E (on ENST00000220888 / NM_001330599.2; = p.Q150E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55227189, COSV55268333; called by muse, mutect2
- TTN | c.85314C>A p.H28438Q (on ENST00000591111; = p.H21014Q on NM_003319.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | PolyPhen benign (0.127); catalogued as COSV60165197; called by muse, mutect2, varscan2
- UBE4B | c.1849A>G p.I617V (on ENST00000343090 / NM_001105562.3; = p.I488V on NM_006048.5) | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs374640200; called by muse, mutect2
- UGT1A3 | c.833del p.G278Afs*89 | Frame Shift Del (DEL) | VAF 53/271 reads (20%) | catalogued as rs1559375297; called by mutect2, pindel, varscan2
- UGT3A1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs375679556; called by muse, mutect2, varscan2
- ZNF112 | c.223A>G p.R75G (on ENST00000337401 / NM_001083335.2; = p.R69G on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs749588315; called by muse, mutect2, varscan2
- ZNF77 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100094465; called by muse, mutect2, varscan2
- ZNF836 | c.2219A>T p.H740L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99078326; called by muse, mutect2
- ABCA13 | c.1295T>A p.L432Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ADAMTS12 | c.4694C>T p.A1565V | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMER1 | c.2228G>T p.R743M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7641G>T p.K2547N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKRD27 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- ANKRD45 | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARHGAP24 | c.2004C>A p.S668R (on ENST00000395184 / NM_001025616.3; = p.S575R on NM_031305.3) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.994); called by muse, mutect2
- ASH1L | c.6471G>T p.W2157C (on ENST00000368346 / NM_001366177.2; = p.W2152C on NM_018489.3) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD2B | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); called by muse, mutect2
- ATP5MD | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP6V1A | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- C1orf112 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C20orf194 | c.3470T>C p.I1157T | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CALHM5 | c.456A>T p.E152D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CBLB | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- CCDC34 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CDH10 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDH20 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFHR5 | c.1167C>A p.C389* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- CFL2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CIZ1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- COL6A6 | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2
- CPED1 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CTNNA2 | c.2273T>G p.L758* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- CTTN | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CYP2E1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- DCAF17 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 140/523 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- DCBLD1 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- DDX54 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- DNAH11 | c.3308G>C p.R1103T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); called by muse, varscan2
- E2F7 | c.1356T>A p.Y452* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- FAM204A | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FAM217A | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- FAT1 | c.5833A>T p.R1945* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- FOXL1 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FOXP4 | c.1702G>T p.G568* (on ENST00000307972 / NM_001012426.1; = p.G555* on NM_138457.3) | Nonsense Mutation (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- FOXP4 | c.1703G>T p.G568V (on ENST00000307972 / NM_001012426.1; = p.G555V on NM_138457.3) | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- FPR1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRB3 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- GIGYF2 | c.3414G>T p.W1138C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GON4L | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- GPR45 | c.244A>T p.M82L | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GRIN2A | c.2760A>T p.R920S | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- IGHE | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- IGKV3-15 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL17A | c.457C>G p.H153D | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNC2 | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); called by muse, mutect2
- KCTD8 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF20B | c.2596G>A p.E866K (on ENST00000371728 / NM_001284259.2; = p.E826K on NM_016195.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- KIF20B | c.5040G>T p.L1680F (on ENST00000371728 / NM_001284259.2; = p.L1640F on NM_016195.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL14 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRT83 | c.585C>G p.Y195* | Nonsense Mutation (SNP) | VAF 125/431 reads (29%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1264A>T p.R422* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | called by muse, mutect2, varscan2
- LAMB4 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2
- LLGL2 | c.2219del p.G740Afs*31 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- MAP1A | c.3056C>A p.S1019Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MARCHF6 | c.2336T>G p.M779R | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MARF1 | c.3375C>G p.I1125M | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEI1 | c.2707G>T p.G903* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- MNDA | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MUC6 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MYH4 | c.5386G>T p.D1796Y | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH4 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NELL1 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, varscan2
- NFKBIZ | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP9 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OR2T33 | c.76T>A p.F26I | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, varscan2
- OR52E6 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.137); called by muse, varscan2
- OR52N1 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL1A | c.2223G>C p.L741F (on ENST00000319481 / NM_080597.4; = p.L228F on NM_018030.4) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- P3H3 | c.1263C>G p.L421= | Splice Region (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- PAK3 | c.1624A>T p.S542C (on ENST00000262836 / NM_001324328.2; = p.S527C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- PAPOLG | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PASK | c.3665A>G p.K1222R | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PDZRN4 | c.2062A>T p.R688W (on ENST00000402685 / NM_001164595.2; = p.R430W on NM_013377.4) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PGAP2 | c.166-8_199del p.X56_splice (on ENST00000463452 / NM_001346398.2; = p.X117_splice on NM_014489.4) | Splice Site (DEL) | VAF 36/256 reads (14%) | called by mutect2, pindel
- PKHD1L1 | c.10385G>A p.G3462E | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PPP3R1 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- PRTG | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYDC2 | c.275G>C p.C92S | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIOK1 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RRAGC | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- RYR3 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SIRPG | c.964A>G p.R322G | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SLC18B1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC44A5 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA2 | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOCS6 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SPATC1 | c.1487T>A p.L496Q | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2
- TAPT1 | c.1454A>G p.N485S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIE1 | c.523dup p.D175Gfs*67 | Frame Shift Ins (INS) | VAF 46/176 reads (26%) | called by mutect2, pindel, varscan2
- TMEM168 | c.903_911del p.G302_F304del | In Frame Del (DEL) | VAF 14/69 reads (20%) | called by pindel, varscan2*
- TNFRSF11A | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TP53 | c.1040_1045dup p.A347_L348dup | In Frame Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- TPTE2 | c.688G>T p.A230S (on ENST00000400230 / NM_199254.2; = p.A153S on NM_130785.3) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV20-1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC5 | c.723G>C p.K241N | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- VWA3A | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WDR44 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- ZNF284 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZNF77 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF77 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- APCDD1L | c.310C>T p.L104= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.1026C>T p.F342= (on ENST00000359920 / NM_001130955.2; = p.F238= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- ARMC5 | c.2475G>A p.Q825= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- ATP10D | c.2163G>T p.L721= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- AXIN1 | c.423G>T p.A141= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- C2CD3 | c.5262C>T p.C1754= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.951C>T p.R317= | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as COSV99387044; called by muse, mutect2, varscan2
- CDR1 | c.183G>A p.T61= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs773964280, COSV100983416; called by muse, mutect2, varscan2
- CEP76 | c.1821T>G p.R607= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs1388028749; called by muse, mutect2, varscan2
- CHI3L1 | c.9G>A p.V3= | Silent (SNP) | VAF 54/218 reads (25%) | called by muse, mutect2, varscan2
- CNST | c.1653T>G p.L551= | Silent (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- COL16A1 | c.1539G>C p.L513= | Silent (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- COL4A2 | c.4731C>A p.P1577= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV64626480, COSV64634335; called by muse, mutect2, varscan2
- CPNE5 | c.153C>T p.T51= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CRY1 | c.633A>T p.P211= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- DNAJC4 | c.6G>A p.P2= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- DNMT3A | c.453A>G p.K151= | Silent (SNP) | VAF 58/355 reads (16%) | called by muse, mutect2, varscan2
- EPHA8 | c.1803G>A p.P601= | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as rs572862634; called by muse, mutect2
- FUT4 | c.1290G>T p.A430= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- GPR176 | c.1152A>G p.T384= | Silent (SNP) | VAF 123/391 reads (31%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1101A>T p.V367= | Silent (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- IL18 | c.168C>G p.L56= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- KRT39 | c.1069C>T p.L357= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as COSV100842214; called by muse, mutect2, varscan2
- MAP2 | c.147A>G p.P49= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- MED13L | c.663A>C p.T221= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99928774; called by muse, mutect2
- MIP | c.10C>T p.L4= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- NCOA6 | c.3753C>G p.L1251= | Silent (SNP) | VAF 13/296 reads (4%) | catalogued as COSV100750017; called by muse, mutect2
- NMT1 | c.84G>A p.E28= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- OR11H12 | c.177C>A p.A59= | Silent (SNP) | VAF 30/250 reads (12%) | catalogued as COSV101612488; called by muse, mutect2, varscan2
- OR2T33 | c.225T>A p.T75= | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as COSV100531896; called by muse, mutect2
- OR5T3 | c.111C>A p.V37= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- PARS2 | c.336C>T p.I112= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs778023056, COSV100988302; called by muse, mutect2
- PDIA5 | c.1470C>T p.S490= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs148193253; called by muse, mutect2, varscan2
- PIP5K1C | c.1422C>G p.A474= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs763569400; called by muse, mutect2, varscan2
- PLTP | c.57C>T p.F19= | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as rs1165365732, COSV100819086; called by muse, mutect2
- POU2F1 | c.2079C>T p.V693= (on ENST00000541643 / NM_001365848.1; = p.V716= on NM_002697.4) | Silent (SNP) | VAF 68/357 reads (19%) | catalogued as COSV54820630, COSV99610699; called by muse, mutect2, varscan2
- PPP1R3A | c.1101T>G p.T367= | Silent (SNP) | VAF 82/209 reads (39%) | called by muse, mutect2, varscan2
- PTH2R | c.1458T>C p.P486= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- PYCR2 | c.759G>T p.L253= | Silent (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.5235C>T p.V1745= | Silent (SNP) | VAF 10/235 reads (4%) | catalogued as COSV99174056; called by muse, mutect2
- RBM33 | c.795G>A p.Q265= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- RCN3 | c.555A>C p.R185= | Silent (SNP) | VAF 60/430 reads (14%) | called by muse, mutect2, varscan2
- SEMG1 | c.132G>A p.K44= | Silent (SNP) | VAF 62/200 reads (31%) | catalogued as rs748841177; called by muse, mutect2, varscan2
- SIM1 | c.423C>T p.T141= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs754523193; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORCS1 | c.1045C>A p.R349= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV53878887, COSV99547749; called by muse, mutect2
- SPATA6L | c.795A>T p.A265= (on ENST00000461761 / NM_001353484.2; = p.A207= on NM_001039395.4 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- STON2 | c.1572A>G p.L524= (on ENST00000649389 / NM_001366849.2; = p.L467= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 95/296 reads (32%) | catalogued as COSV99964470; called by muse, mutect2, varscan2
- TEX29 | c.261A>G p.K87= | Silent (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- TUBB | c.297C>T p.N99= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- VN1R2 | c.504A>C p.A168= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- WWP2 | c.87C>G p.P29= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- ZBTB20 | c.492G>T p.R164= (on ENST00000474710 / NM_001164342.2; = p.R91= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- ZEB2 | c.2745C>T p.T915= | Silent (SNP) | VAF 50/252 reads (20%) | called by muse, mutect2, varscan2
- ZEB2 | c.522T>A p.I174= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- ZNF683 | c.753G>A p.E251= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1297565492; called by muse, mutect2, varscan2
- ZNF804A | c.2889G>A p.Q963= | Silent (SNP) | VAF 5/127 reads (4%) | catalogued as COSV56469084; called by muse, mutect2
- AC024940.1 | n.4488T>C | RNA (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- DEPDC5 | c.*995G>A | 3'UTR (SNP) | VAF 28/601 reads (5%) | catalogued as rs746564947, COSV56698255; called by muse, mutect2
- MIR133A2 | n.52C>G | RNA (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- MIR20A | n.25A>G | RNA (SNP) | VAF 59/260 reads (23%) | called by muse, mutect2, varscan2
- NBPF7 | n.631G>T | RNA (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- NBPF7 | n.630G>T | RNA (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- SPATA19 | c.-2A>T | 5'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100141097; called by muse, mutect2, varscan2
- ZFP90 | c.-2G>C | 5'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100788145; called by muse, mutect2
